Somatic mutation profile of tumor specimen TCGA-BQ-5875-01A (aliquot TCGA-BQ-5875-01A-11D-1589-08) from TCGA case TCGA-BQ-5875, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 66.1 years (24,153 days).
Specimen TCGA-BQ-5875-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79b0de7c-650e-4b13-816c-2f149706ba95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5875-11A (Solid Tissue Normal), aliquot TCGA-BQ-5875-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afe93680-adbe-416b-9cf5-defad5693b78

The open-access MAF lists 74 somatic variants for this specimen: 55 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 16, Frame Shift Del 7, Nonsense Mutation 4, Intron 2, Splice Site 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.3677G>T p.G1226V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV64676590; called by muse, mutect2, varscan2
- ACAP1 | c.1289G>A p.W430* | Nonsense Mutation (SNP) | VAF 37/110 reads (34%) | catalogued as COSV50139882; called by muse, mutect2, varscan2
- ADAM17 | c.2157G>A p.M719I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV60401201; called by muse, mutect2, varscan2
- AEBP2 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV56865719; called by muse, mutect2, varscan2
- ARRB1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV63577096; called by muse, mutect2, varscan2
- ATAD5 | c.960G>C p.K320N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV58977728; called by muse, mutect2, varscan2
- BAP1 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56231274, COSV56239037; called by muse, mutect2, varscan2
- CASP5 | c.181A>C p.K61Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV52830877; called by muse, mutect2, varscan2
- CDC20B | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV57055730, COSV99697441; called by muse, mutect2, varscan2
- CDK10 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779865826, COSV58415648; called by muse, mutect2, varscan2
- CEP350 | c.8357A>T p.Q2786L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV62608243; called by muse, mutect2, varscan2
- CX3CL1 | c.113A>G p.K38R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV50056660; called by muse, mutect2, varscan2
- CYBRD1 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58427607; called by muse, mutect2
- CYRIA | c.851T>A p.I284K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62866583; called by muse, mutect2
- DCAF4 | c.678G>A p.K226= | Splice Region (SNP) | VAF 50/141 reads (35%) | catalogued as COSV62320314; called by muse, mutect2
- DNAJC16 | c.2087G>A p.G696D | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65436151; called by muse, varscan2
- EEF2K | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.024); catalogued as COSV53785788; called by muse, mutect2, varscan2
- FMO4 | c.962T>C p.I321T | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1244791411, COSV63001767; called by muse, mutect2, varscan2
- FOXP2 | c.1647+1G>A p.X549_splice | Splice Site (SNP) | VAF 20/50 reads (40%) | catalogued as COSV63491915; called by muse, mutect2, varscan2
- GDE1 | c.748T>G p.F250V | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as COSV62059807; called by muse, mutect2, varscan2
- IL1R2 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV60206622, COSV60208931; called by muse, mutect2, varscan2
- ITGB2 | c.2300T>G p.L767R (on ENST00000302347; = p.L743R on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as COSV56612446; called by muse, mutect2, varscan2
- KCNA2 | c.881G>T p.R294L | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100315917, COSV60369586; called by muse, mutect2, varscan2
- KCTD8 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.241); catalogued as COSV63594267; called by muse, mutect2, varscan2
- KDM5A | c.4259C>G p.P1420R | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV66992304, COSV66995054; called by muse, mutect2, varscan2
- LRRC37B | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58954182; called by muse, mutect2, varscan2
- MFSD11 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 100/207 reads (48%) | catalogued as COSV60627397; called by muse, mutect2, varscan2
- MRPL54 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV57462644; called by muse, mutect2, varscan2
- NCKAP1L | c.727T>G p.S243A | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.267); catalogued as COSV53210919; called by muse, mutect2, varscan2
- NDUFB2 | c.199T>A p.F67I | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52595422, COSV52596057; called by muse, mutect2, varscan2
- NF2 | c.396C>A p.Y132* | Nonsense Mutation (SNP) | VAF 34/50 reads (68%) | catalogued as COSV104404784, COSV58528779; called by muse, mutect2, varscan2
- NFATC3 | c.2147C>A p.P716Q | Missense Mutation (SNP) | VAF 87/157 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV60477982, COSV60479641; called by muse, mutect2, varscan2
- NINL | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs771378401, COSV54007268; called by muse, mutect2, varscan2
- NPRL2 | c.518A>T p.D173V | Missense Mutation (SNP) | VAF 99/136 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV51601297, COSV51603570; called by muse, mutect2, varscan2
- PPAT | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51706113; called by muse, mutect2, varscan2
- PRAG1 | c.1807G>T p.G603C | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV100422174, COSV58165380; called by muse, mutect2, varscan2
- SAAL1 | c.1414G>C p.V472L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as COSV55516835; called by muse, mutect2, varscan2
- SETD2 | c.7405A>T p.K2469* | Nonsense Mutation (SNP) | VAF 60/71 reads (85%) | catalogued as COSV57435556; called by muse, mutect2, varscan2
- SLC12A4 | c.1991G>C p.G664A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); catalogued as COSV50454366, COSV99863222; called by muse, mutect2, varscan2
- SLC4A10 | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV55794350; called by muse, mutect2, varscan2
- SPAG17 | c.5318T>A p.V1773D | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV60465306; called by muse, mutect2, varscan2
- STAC | c.1196T>G p.L399R | Missense Mutation (SNP) | VAF 52/68 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56216287; called by muse, mutect2, varscan2
- SUFU | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV64015942; called by muse, mutect2, varscan2
- SYT4 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54903311; called by muse, mutect2, varscan2
- TLL2 | c.2362G>T p.A788S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV63574942; called by muse, mutect2, varscan2
- ZBTB11 | c.2021C>G p.T674R | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57246459; called by muse, mutect2, varscan2
- ZFP14 | c.941G>A p.C314Y | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54204172; called by muse, mutect2, varscan2
- ZNF547 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.435); catalogued as COSV56581621; called by muse, mutect2, varscan2
- DNAJC16 | c.2172del p.S725Rfs*31 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | called by pindel, varscan2
- MCTS1 | c.45_46del p.Q16Vfs*7 | Frame Shift Del (DEL) | VAF 29/118 reads (25%) | called by mutect2, pindel*, varscan2*
- OR51A2 | c.475_481del p.L159Sfs*5 | Frame Shift Del (DEL) | VAF 58/152 reads (38%) | called by mutect2, varscan2
- RERE | c.1321del p.T441Pfs*45 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- STAG2 | c.974_977del p.N325Tfs*4 | Frame Shift Del (DEL) | VAF 56/166 reads (34%) | called by mutect2, pindel, varscan2
- TMEM144 | c.313del p.T105Lfs*23 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- ZNF30 | c.738del p.K246Nfs*124 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- ADGRB2 | c.2847C>T p.T949= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs1351922836, COSV57077488; called by muse, mutect2, varscan2
- AFF4 | c.465A>C p.S155= | Silent (SNP) | VAF 58/135 reads (43%) | catalogued as COSV54798142; called by muse, mutect2, varscan2
- ANKLE1 | c.1641C>T p.A547= (on ENST00000394458; = p.A493= on NM_152363.6) | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as rs111432888, COSV66732396; called by muse, mutect2, varscan2
- CADM3 | c.1071G>A p.R357= (on ENST00000368125 / NM_001127173.3; = p.R391= on NM_021189.5) | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1305560909, COSV63676394; called by muse, mutect2
- CHMP1A | c.192G>A p.R64= | Silent (SNP) | VAF 55/189 reads (29%) | catalogued as COSV53684230; called by muse, mutect2, varscan2
- GAB2 | c.1461C>T p.D487= (on ENST00000361507 / NM_080491.3; = p.D449= on NM_012296.3) | Silent (SNP) | VAF 67/216 reads (31%) | catalogued as rs749482196, COSV60870274; called by muse, mutect2, varscan2
- LEPROT | c.199C>A p.R67= | Silent (SNP) | VAF 14/179 reads (8%) | catalogued as COSV60761405; called by muse, mutect2
- PFKM | c.2028C>A p.A676= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as rs1489568698, COSV56659662; called by muse, mutect2, varscan2
- PLEC | c.6051G>A p.L2017= (on ENST00000322810 / NM_201380.4; = p.L1907= on NM_000445.5) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs782152422, COSV59678871; called by muse, mutect2, varscan2
- POLR2L | c.148C>T p.L50= | Silent (SNP) | VAF 47/159 reads (30%) | catalogued as COSV58990735; called by muse, mutect2, varscan2
- SLC4A10 | c.534T>G p.T178= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV55794368; called by muse, mutect2, varscan2
- SLC9A7 | c.1683T>A p.V561= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV60381860, COSV60382851; called by muse, mutect2, varscan2
- TTC7A | c.2379C>T p.G793= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV55414332; called by muse, mutect2, varscan2
- VPS13A | c.6984T>A p.A2328= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV62436289; called by muse, mutect2, varscan2
- ZNF225 | c.1144A>C p.R382= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as COSV53472793; called by muse, mutect2, varscan2
- ZNF395 | c.1152G>T p.P384= | Silent (SNP) | VAF 58/166 reads (35%) | catalogued as COSV60429921; called by muse, mutect2, varscan2
- DST | c.4297-1487G>A | Intron (SNP) | VAF 41/99 reads (41%) | catalogued as rs148062292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT18P55 | n.599_600insT | RNA (INS) | VAF 28/74 reads (38%) | called by mutect2, pindel, varscan2
- PIGF | c.546+4317A>G | Intron (SNP) | VAF 21/42 reads (50%) | catalogued as COSV99851335; called by muse, mutect2, varscan2
